Gene-level copy-number profile of tumor specimen ALCH-B1W7-TTP1-A from ALCHEMIST case ALCH-B1W7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,036 days).
Specimen ALCH-B1W7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d924885d-086a-4552-b91c-4dd695beb786.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1W7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/3192cb32-3bb5-4854-a60a-e3d346a77687

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 624; copy number 1: 5,299; copy number 2: 44,328; copy number 3: 6,133; copy number 4: 2,033; copy number 5: 456; copy number 6: 11; copy number 10: 3; copy number 11: 1; copy number 14: 1; copy number 21: 1; copy number 33: 1; copy number 39: 1.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,946,471–10,991,797, 2 genes: C1orf127, CFL1P6.
- chr1:12,926,162–12,928,253, 1 gene (within-gene range 0–1): PRAMEF29P.
- chr1:13,172,455–13,248,652, 4 genes: PRAMEF9, PRAMEF13, PRAMEF18, PRAMEF31P.
- chr1:13,279,125–13,285,174, 2 genes: RNU6-771P, PRAMEF8.
- chr2:90,121,786–90,122,564, 1 gene (within-gene range 0–2): IGKV2D-14.
- chr5:69,492,292–69,558,104, 2 genes (within-gene range 0–1): OCLN, RNU6-724P.
- chr6:17,381,367–17,382,120, 1 gene: AL034372.1.
- chr6:73,362,658–73,395,133, 5 genes (within-gene range 0–2): KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8.
- chr6:107,065,182–107,115,515, 1 gene: BEND3.
- chr14:34,561,093–34,630,160, 2 genes (within-gene range 0–1): SNX6, RPS19P3.
- chr15:20,803,505–20,866,314, 6 genes: AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P.
- chr15:21,015,048–22,282,872, 69 genes (broad region; genes not listed).
- chr15:22,770,523–22,829,789, 2 genes (within-gene range 0–1): AC011767.1, NIPA1.
- chr15:23,430,839–23,447,243, 2 genes: HERC2P6, GOLGA6L2.
- chr15:65,229,861–65,229,967, 1 gene: RNU6-686P.
- chr15:65,285,461–65,285,591, 1 gene (within-gene range 0–1): SNORA24B.
- chr15:65,327,127–65,378,002, 1 gene: IGDCC3.
- chr16:4,560,001–4,563,128, 2 genes (within-gene range 0–1): AC023830.2, SUB1P3.
- chr16:88,809,339–88,811,937, 1 gene: APRT.
- chr20:31,637,912–31,645,006, 1 gene: COX4I2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 475 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,108,056–32,176,568, 2 genes, copy number 5: KPNA6, AL049795.2.
- chr4:54,657,918–54,740,715, 1 gene, copy number 5: KIT.
- chr7:99,546,300–99,558,536, 1 gene, copy number 6 (within-gene range 2–6): FAM200A.
- chr8:128,405,269–128,564,679, 1 gene, copy number 5: LINC00824.
- chr11:115,169,218–116,774,205, 25 genes, copy number 5–6 (within-gene range 4–6): CADM1, AP000465.1, AP000462.3, AP000462.1, AP000462.2, AP003174.2, AP003174.3, RPL12P46, AP003174.1, AP000997.1, AP000997.2, AP000997.3, AP000997.4, LINC02698, AP002991.1, AP002991.2, LINC00900, LINC02703, AP000797.2, AP000797.1, LINC02151, AP000770.1, LINC02702, BUD13, AP006216.1.
- chr11:116,843,402–121,113,108, 145 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:121,238,304–135,075,908, 288 genes, copy number 5–6 (broad region; genes not listed).
- chr14:105,489,855–105,499,575, 1 gene, copy number 5 (within-gene range 2–5): TEDC1.
- chr14:105,583,731–105,601,728, 2 genes, copy number 6–14 (within-gene range 4–14): IGHA2, IGHE.
- chr16:769,119–769,443, 1 gene, copy number 33 (within-gene range 2–33): AL031258.1.
- chr16:784,974–800,737, 3 genes, copy number 10 (within-gene range 6–10): RPUSD1, CHTF18, GNG13.
- chr16:88,856,220–88,866,660, 2 genes, copy number 5 (within-gene range 3–5): TRAPPC2L, PABPN1L.
- chr16:89,195,761–89,201,651, 1 gene, copy number 39: SLC22A31.
- chr19:1,228,287–1,239,522, 2 genes, copy number 11–21 (within-gene range 3–21): CBARP, AC004221.1.

Autosomal genes at a single copy (total copy number 1): 2,960. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
